Somatic mutation profile of tumor specimen TCGA-FS-A1YW-06A (aliquot TCGA-FS-A1YW-06A-11D-A197-08) from TCGA case TCGA-FS-A1YW, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 64.9 years (23,715 days).
Specimen TCGA-FS-A1YW-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f14f1dc2-a7d6-4eee-b2b0-7d5c75281a64.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1YW-10A (Blood Derived Normal), aliquot TCGA-FS-A1YW-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afe374a5-fb81-4b10-995d-554bded82e61

The open-access MAF lists 184 somatic variants for this specimen: 121 protein-altering or splice-affecting, 59 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 59, Nonsense Mutation 8, Splice Region 2, Splice Site 2, RNA 2, Frame Shift Del 1, Frame Shift Ins 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 80/179 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABLIM3 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58649327; called by muse, mutect2, varscan2
- AK7 | c.1937T>A p.V646E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764796300, COSV50884171; called by muse, mutect2, varscan2
- ANKRD12 | c.6148C>T p.L2050F | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1393980167, COSV50853516; called by muse, mutect2, varscan2
- ARHGAP11A | c.3022C>T p.P1008S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277063, COSV55708747; called by muse, mutect2, varscan2
- ARHGEF11 | c.3824C>G p.P1275R | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.189); catalogued as COSV59359103; called by muse, mutect2, varscan2
- ARMC5 | c.1817C>T p.P606L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.135); catalogued as rs773596341, COSV51660280; called by muse, mutect2, varscan2
- ATP13A5 | c.3206G>A p.R1069Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764104661, COSV60867915; called by muse, mutect2, varscan2
- ATP2A2 | c.2503C>T p.R835C | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1386923520, COSV57876447; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs755337830, COSV59481089; called by muse, mutect2, varscan2
- B3GNT3 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV57954270; called by muse, mutect2, varscan2
- BASP1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.111); catalogued as COSV59474009; called by muse, mutect2, varscan2
- BMP2K | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.23); PolyPhen benign (0.345); catalogued as COSV58599952; called by muse, mutect2, varscan2
- BRD1 | c.3092C>T p.A1031V (on ENST00000216267 / NM_001349940.1; = p.A1162V on NM_001304808.3) | Missense Mutation (SNP) | VAF 68/94 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.404); catalogued as COSV53462143; called by muse, mutect2, varscan2
- C16orf78 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as rs867806225, COSV54558762; called by muse, mutect2, varscan2
- CDC14A | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs778051201, COSV60556049; called by muse, mutect2, varscan2
- CIB3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.082); catalogued as COSV54167827; called by muse, mutect2, varscan2
- CLCN3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV61626813; called by muse, mutect2, varscan2
- COL5A1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV65670041; called by muse, mutect2, varscan2
- CPEB4 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 55/168 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99437785; called by muse, mutect2, varscan2
- CR2 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs759188564, COSV65507714; called by muse, mutect2, varscan2
- CRMP1 | c.811+1G>A p.X271_splice | Splice Site (SNP) | VAF 97/229 reads (42%) | catalogued as COSV61483432; called by muse, mutect2, varscan2
- CTR9 | c.2570T>C p.L857P | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.207); catalogued as COSV63729808; called by muse, mutect2, varscan2
- CUX2 | c.3676G>A p.E1226K | Missense Mutation (SNP) | VAF 65/156 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55645814; called by muse, mutect2, varscan2
- CYP2C9 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs763531925, COSV53253425; called by muse, mutect2, varscan2
- CYP4A22 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs780190981, COSV53737797; called by muse, mutect2, varscan2
- CYP4A22 | c.1283_1286del p.L428Rfs*36 | Frame Shift Del (DEL) | VAF 113/312 reads (36%) | catalogued as COSV53741873; called by mutect2, varscan2
- CYP7A1 | c.800T>A p.L267* | Nonsense Mutation (SNP) | VAF 180/308 reads (58%) | catalogued as COSV56966122; called by muse, mutect2, varscan2
- DDR2 | c.933T>G p.S311R | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.025); catalogued as COSV63374872; called by muse, mutect2, varscan2
- DEF8 | c.560C>T p.P187L (on ENST00000268676 / NM_207514.3; = p.P126L on NM_017702.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.706); catalogued as COSV51921718; called by muse, mutect2, varscan2
- DMRTC2 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.372); catalogued as COSV54188723; called by muse, mutect2, varscan2
- DNAH5 | c.2758G>A p.G920R | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV54255718; called by muse, mutect2, varscan2
- DNAI3 | c.2494A>C p.K832Q | Missense Mutation (SNP) | VAF 72/167 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.249); catalogued as COSV54006672; called by muse, mutect2, varscan2
- ECSIT | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52939967; called by muse, mutect2, varscan2
- FAM131A | c.47T>G p.F16C | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99659077; called by muse, mutect2, varscan2
- FGL1 | c.95G>A p.R32Q | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as rs140117264; called by muse, mutect2, varscan2
- FPR1 | c.31A>C p.I11L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV59054040; called by muse, mutect2, varscan2
- FREM2 | c.5504C>T p.A1835V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV54854434; called by muse, mutect2, varscan2
- FRMPD1 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | catalogued as rs756821118, COSV63384024, COSV63384031; called by muse, mutect2, varscan2
- FSIP2 | c.16564G>A p.E5522K | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV58086231; called by muse, mutect2, varscan2
- FUT9 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs866379874, COSV56144259; called by muse, mutect2, varscan2
- GALNT17 | c.1561C>T p.L521F | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.962); catalogued as COSV61194696; called by muse, mutect2, varscan2
- GLRB | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 51/134 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs866482989, COSV52412584, COSV52414164; called by muse, mutect2, varscan2
- H2AC1 | c.82G>A p.V28I | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs200120159, COSV51238833; called by muse, mutect2, varscan2
- H2BW1 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as rs1372913053, COSV54220215, COSV99475140; called by muse, mutect2
- HEXIM2 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.12); catalogued as rs779522379, COSV100218011; called by muse, mutect2, varscan2
- HNF4G | c.520G>A p.A174T (on ENST00000354370 / NM_001330561.2; = p.A221T on NM_004133.5) | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV62974307; called by muse, mutect2, varscan2
- IGSF10 | c.2384A>C p.D795A | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as COSV56792565; called by muse, mutect2, varscan2
- ITIH1 | c.2607G>A p.R869= | Splice Region (SNP) | VAF 8/31 reads (26%) | catalogued as COSV56258911; called by muse, mutect2, varscan2
- KALRN | c.7730C>T p.A2577V (on ENST00000360013 / NM_001024660.4; = p.A880V on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.995); catalogued as COSV52265639; called by muse, mutect2, varscan2
- KCNK9 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 88/120 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV57287172, COSV57289072; called by muse, mutect2, varscan2
- KCNK9 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as rs1237927464, COSV57278660; called by muse, mutect2
- KCNN3 | c.1940C>T p.S647F (on ENST00000618040 / NM_001204087.1; = p.S632F on NM_002249.6) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV55228013; called by muse, mutect2, varscan2
- KMT2A | c.9449G>A p.S3150N | Missense Mutation (SNP) | VAF 174/191 reads (91%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV63293217; called by muse, mutect2, varscan2
- KNL1 | c.172C>T p.R58* | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as COSV61152771; called by muse, mutect2, varscan2
- KSR2 | c.551C>T p.P184L | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs1189248092, COSV60396206; called by muse, mutect2, varscan2
- LAMA3 | c.7021A>G p.K2341E (on ENST00000313654 / NM_198129.4; = p.K732E on NM_000227.6) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV52544365; called by muse, mutect2, varscan2
- LAYN | c.682G>A p.E228K (on ENST00000375615 / NM_001258390.1; = p.E220K on NM_178834.5) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV65105671; called by muse, mutect2, varscan2
- LIM2 | c.462G>A p.G154= (on ENST00000596399 / NM_001161748.2; = p.G196= on NM_030657.4) | Splice Region (SNP) | VAF 10/23 reads (43%) | catalogued as rs757302099, COSV55742585; called by muse, mutect2, varscan2
- LRP1B | c.13507G>A p.D4503N | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV67239110; called by muse, mutect2, varscan2
- LRRC4C | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53434224; called by muse, mutect2, varscan2
- LY96 | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs746411046, COSV53025190, COSV99514265; called by muse, mutect2, varscan2
- MARCHF11 | c.1135C>T p.R379W | Missense Mutation (SNP) | VAF 80/184 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs537978378, COSV60135731; called by muse, mutect2, varscan2
- MCTP2 | c.2498G>A p.R833Q | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs187187495, COSV63292683; called by muse, mutect2, varscan2
- MEGF8 | c.7879G>A p.A2627T (on ENST00000251268 / NM_001271938.2; = p.A2560T on NM_001410.3) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs779762562, COSV52103496; called by muse, mutect2, varscan2
- MPO | c.1411G>A p.A471T | Missense Mutation (SNP) | VAF 81/166 reads (49%) | SIFT tolerated (0.48); PolyPhen benign (0.054); catalogued as COSV56568286; called by muse, mutect2, varscan2
- MROH9 | c.1684C>T p.P562S | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV100883099; called by muse, mutect2, varscan2
- MTMR1 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as COSV64900012; called by muse, mutect2, varscan2
- MUC5B | c.9400A>T p.I3134F | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.178); catalogued as COSV71596022; called by muse, mutect2, varscan2
- MXRA5 | c.8095C>T p.R2699C | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54252600; called by muse, mutect2, varscan2
- NBEA | c.4513C>T p.Q1505* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV59827200; called by muse, varscan2
- NECAB1 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 27/44 reads (61%) | catalogued as rs774568110, COSV101341178, COSV70244769; called by muse, mutect2, varscan2
- NUMB | c.202-1G>A p.X68_splice | Splice Site (SNP) | VAF 27/70 reads (39%) | catalogued as COSV61832490; called by muse, mutect2, varscan2
- OR4F6 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 113/271 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as rs745953823, COSV61026300; called by muse, mutect2, varscan2
- OR51B2 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV60915972; called by muse, mutect2, varscan2
- OR52B2 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV73209680, COSV73209694; called by muse, mutect2, varscan2
- OR5B21 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.424); catalogued as rs140880239, COSV64482318; called by muse, mutect2, varscan2
- OR6B3 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 98/125 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV60112553; called by muse, mutect2, varscan2
- OR6C74 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.056); catalogued as rs777439706, COSV59605795; called by muse, mutect2, varscan2
- OTUD7A | c.1734C>G p.S578R (on ENST00000307050 / NM_001382637.1; = p.S571R on NM_130901.3) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); catalogued as COSV61044054; called by muse, mutect2, varscan2
- PATJ | c.5206G>A p.D1736N | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64507068; called by muse, mutect2, varscan2
- PCDHA1 | c.274C>A p.R92S | Missense Mutation (SNP) | VAF 60/123 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV65374900, COSV65377245; called by muse, mutect2, varscan2
- PCDHA6 | c.2279C>T p.S760F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as rs782407463, COSV65343143; called by muse, varscan2
- PCDHB2 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.564); catalogued as rs560781528, COSV50575108, COSV50582171; called by muse, mutect2, varscan2
- PCDHB9 | c.488G>T p.G163V | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782162634, COSV53384453; called by muse, mutect2, varscan2
- PCDHGA6 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs765909880, COSV54044403, COSV99535533; called by muse, varscan2
- PCSK5 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 44/60 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238436012, COSV65097434; called by muse, mutect2, varscan2
- PDE5A | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53353754; called by muse, mutect2, varscan2
- PDZRN4 | c.1351G>A p.D451N (on ENST00000402685 / NM_001164595.2; = p.D193N on NM_013377.4) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54190945, COSV54212779; called by muse, mutect2, varscan2
- PER1 | c.80C>T p.S27F | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57920761, COSV57922304; called by muse, mutect2, varscan2
- PIGG | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56321900; called by muse, mutect2, varscan2
- PIGK | c.178C>T p.R60* | Nonsense Mutation (SNP) | VAF 47/132 reads (36%) | catalogued as rs752134431, COSV63063789; called by muse, mutect2, varscan2
- PLCH1 | c.1345C>T p.H449Y (on ENST00000340059 / NM_001130960.2; = p.H461Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/186 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58211122; called by muse, mutect2, varscan2
- PLPPR1 | c.439G>C p.V147L | Missense Mutation (SNP) | VAF 37/53 reads (70%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as COSV66458215; called by muse, mutect2, varscan2
- PRR27 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV60640630; called by muse, mutect2, varscan2
- PSG3 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 72/295 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.02); catalogued as rs755758787, COSV100549241; called by muse, mutect2, varscan2
- PSMB5 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as COSV57801404; called by muse, mutect2, varscan2
- PTPRC | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.037); catalogued as rs142046206; called by muse, mutect2, varscan2
- PTPRR | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV51749477; called by muse, mutect2, varscan2
- RIMBP2 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55485518; called by muse, mutect2, varscan2
- RPL7 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs1037661081, COSV53583845; called by muse, mutect2, varscan2
- SAMD3 | c.271T>G p.Y91D | Missense Mutation (SNP) | VAF 25/37 reads (68%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV60778160; called by muse, mutect2, varscan2
- SCN11A | c.3338G>A p.G1113E | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56573490; called by muse, mutect2, varscan2
- SGO2 | c.2936C>T p.S979F | Missense Mutation (SNP) | VAF 25/33 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as COSV63418503; called by muse, mutect2, varscan2
- SLC28A2 | c.1564T>A p.S522T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.812); catalogued as COSV61665451; called by muse, varscan2
- SLC9C2 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.046); catalogued as rs267598172, COSV62945331; called by muse, mutect2, varscan2
- SLIT2 | c.3634C>T p.R1212W | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs1244297047, COSV56563858; called by muse, mutect2, varscan2
- SPINK5 | c.1498C>T p.R500W | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs201611101; called by muse, mutect2, varscan2
- SSH2 | c.3108C>G p.S1036R | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV52182343; called by muse, mutect2, varscan2
- SYT9 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as COSV59615603; called by muse, mutect2, varscan2
- THBS3 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV57427067; called by muse, mutect2, varscan2
- TRERF1 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.052); catalogued as COSV61678716; called by muse, mutect2, varscan2
- TRIM67 | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV64159834; called by muse, mutect2, varscan2
- TUBB8 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV59118239; called by muse, mutect2, varscan2
- TXNDC2 | c.538C>T p.P180S (on ENST00000306084 / NM_001098529.2; = p.P113S on NM_032243.6) | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.977); catalogued as rs754376046, COSV60152486; called by muse, varscan2
- WIF1 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV54136406; called by muse, mutect2, varscan2
- WRN | c.4133C>T p.S1378F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV53308202; called by muse, mutect2, varscan2
- XKR4 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59341750; called by muse, mutect2, varscan2
- ZNF28 | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as rs745591883, COSV60423169; called by muse, mutect2, varscan2
- ZNF415 | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.207); catalogued as COSV54705806; called by muse, mutect2, varscan2
- AL713999.2 | c.284dup p.S96Vfs*38 | Frame Shift Ins (INS) | VAF 30/65 reads (46%) | called by mutect2, pindel, varscan2
- ATP6V0A4 | c.1008G>A p.K336= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV59474438, COSV59481098; called by muse, mutect2, varscan2
- BORA | c.465T>A p.A155= (on ENST00000613797; = p.A80= on NM_024808.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as COSV64695982; called by muse, mutect2, varscan2
- C10orf71 | c.1983G>A p.E661= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV60514134; called by muse, mutect2
- CACNA1E | c.6270G>A p.K2090= (on ENST00000367573 / NM_001205293.3; = p.K2047= on NM_000721.4) | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as rs748894211, COSV62432309; called by muse, mutect2, varscan2
- CASP14 | c.183C>T p.F61= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs377160369; called by muse, mutect2, varscan2
- CDH8 | c.288C>T p.I96= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV54845324, COSV54848241; called by muse, mutect2, varscan2
- CLVS1 | c.12C>T p.V4= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV57983027; called by muse, mutect2, varscan2
- COQ6 | c.342C>T p.A114= | Silent (SNP) | VAF 53/117 reads (45%) | catalogued as COSV53178223; called by muse, mutect2, varscan2
- CPEB4 | c.906C>G p.G302= | Silent (SNP) | VAF 56/173 reads (32%) | catalogued as COSV99437783; called by muse, mutect2, varscan2
- CSNK1D | c.306C>T p.L102= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs754377044, COSV53927675; called by muse, mutect2, varscan2
- EPHX1 | c.201C>T p.I67= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as rs750062692, COSV55304416; called by muse, mutect2, varscan2
- FREM2 | c.5505C>T p.A1835= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99751348; called by muse, mutect2, varscan2
- GPR137C | c.493C>T p.L165= | Silent (SNP) | VAF 46/94 reads (49%) | catalogued as COSV58707326; called by muse, varscan2
- GPR4 | c.183C>T p.I61= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV59917353, COSV59918636; called by muse, mutect2, varscan2
- HEXIM2 | c.162G>A p.E54= | Silent (SNP) | VAF 65/174 reads (37%) | catalogued as rs755426705, COSV100218010; called by muse, mutect2, varscan2
- HNF1B | c.1266C>T p.L422= | Silent (SNP) | VAF 188/473 reads (40%) | called by muse, mutect2, varscan2
- HUWE1 | c.3594C>T p.F1198= | Silent (SNP) | VAF 25/27 reads (93%) | catalogued as COSV53366142; called by muse, mutect2, varscan2
- IRGQ | c.1794C>T p.H598= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV60670100; called by muse, mutect2
- KALRN | c.8820C>T p.P2940= (on ENST00000360013 / NM_001024660.4; = p.P1243= on NM_007064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV52265659; called by muse, mutect2, varscan2
- LRP3 | c.288C>T p.S96= | Silent (SNP) | VAF 53/130 reads (41%) | catalogued as rs1466693117, COSV53507849; called by muse, mutect2, varscan2
- MDN1 | c.15096C>T p.S5032= | Silent (SNP) | VAF 58/199 reads (29%) | catalogued as COSV65531412; called by muse, mutect2, varscan2
- MKRN3 | c.168C>T p.A56= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV58812516; called by muse, mutect2, varscan2
- MUC16 | c.41691G>A p.L13897= | Silent (SNP) | VAF 39/119 reads (33%) | catalogued as COSV66695062; called by muse, mutect2, varscan2
- NIN | c.3912C>T p.F1304= | Silent (SNP) | VAF 52/121 reads (43%) | catalogued as rs556223546, COSV55408458; called by muse, mutect2, varscan2
- OR10T2 | c.408C>T p.I136= | Silent (SNP) | VAF 48/115 reads (42%) | catalogued as rs771683670, COSV57781470; called by muse, mutect2, varscan2
- OR2A14 | c.456C>T p.F152= | Silent (SNP) | VAF 123/278 reads (44%) | catalogued as COSV68718394; called by muse, mutect2, varscan2
- OR2Z1 | c.618C>T p.I206= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV60692728; called by muse, mutect2, varscan2
- OR51E2 | c.867C>T p.I289= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV67808927; called by muse, mutect2, varscan2
- OR6C1 | c.117G>A p.G39= | Silent (SNP) | VAF 31/65 reads (48%) | catalogued as COSV65574572; called by muse, mutect2, varscan2
- OR9G4 | c.186C>T p.F62= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV57250057; called by muse, mutect2, varscan2
- PCDHB11 | c.120G>A p.Q40= | Silent (SNP) | VAF 36/104 reads (35%) | catalogued as COSV53384456; called by muse, mutect2, varscan2
- PDE2A | c.1140C>T p.T380= | Silent (SNP) | VAF 54/259 reads (21%) | catalogued as rs766108349, COSV57814627; called by muse, mutect2, varscan2
- PLEKHG4B | c.2325C>T p.S775= (on ENST00000283426; = p.S1131= on NM_052909.5) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs1475289112, COSV52056100; called by muse, mutect2, varscan2
- PLEKHH1 | c.453C>T p.S151= | Silent (SNP) | VAF 28/55 reads (51%) | catalogued as COSV61288201; called by muse, mutect2, varscan2
- POM121L12 | c.522C>T p.T174= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV68693177; called by muse, mutect2, varscan2
- PRAMEF20 | c.492C>T p.F164= | Silent (SNP) | VAF 232/307 reads (76%) | called by muse, mutect2, varscan2
- PTPRC | c.2637G>A p.V879= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as rs772752719, COSV61421323; called by muse, mutect2, varscan2
- RDH16 | c.408G>A p.V136= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV62458866; called by muse, mutect2, varscan2
- RFWD3 | c.633T>C p.S211= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV63099590; called by muse, mutect2, varscan2
- RNF17 | c.3879C>T p.L1293= | Silent (SNP) | VAF 92/250 reads (37%) | catalogued as COSV55052867; called by muse, mutect2, varscan2
- SBF1 | c.1569G>A p.K523= | Silent (SNP) | VAF 47/58 reads (81%) | catalogued as COSV62370749; called by muse, mutect2, varscan2
- SDK2 | c.5724C>T p.F1908= | Silent (SNP) | VAF 27/42 reads (64%) | catalogued as rs373715499; called by muse, mutect2, varscan2
- SEMA5A | c.2763C>T p.I921= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs1197318713, COSV66806585; called by muse, mutect2, varscan2
- SH3TC1 | c.603C>T p.T201= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as rs750110207, COSV55290531; called by muse, mutect2, varscan2
- SLC13A5 | c.978G>A p.L326= | Silent (SNP) | VAF 86/106 reads (81%) | catalogued as COSV53425434; called by muse, mutect2, varscan2
- SPHKAP | c.597G>A p.L199= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs555883155, COSV60896103; called by muse, mutect2, varscan2
- SPTA1 | c.5764T>C p.L1922= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as COSV63760578; called by muse, mutect2, varscan2
- TAAR5 | c.718C>T p.L240= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as rs188569215; called by muse, mutect2, varscan2
- TAAR5 | c.717C>T p.S239= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV99237016; called by muse, mutect2, varscan2
- TRABD2A | c.1128C>T p.I376= (on ENST00000409520 / NM_001277053.2; = p.I327= on NM_001080824.3) | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as rs767937726, COSV52874331, COSV52885740; called by muse, mutect2, varscan2
- TTN | c.74301C>T p.N24767= (on ENST00000591111; = p.N17343= on NM_003319.4) | Silent (SNP) | VAF 46/63 reads (73%) | catalogued as COSV60383396; called by muse, mutect2, varscan2
- TXK | c.1182G>A p.R394= | Silent (SNP) | VAF 36/79 reads (46%) | catalogued as COSV51920068; called by muse, mutect2, varscan2
- UPF1 | c.2061C>T p.A687= (on ENST00000599848 / NM_001297549.2; = p.A676= on NM_002911.4) | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV53202584; called by muse, mutect2, varscan2
- VARS1 | c.2340C>T p.L780= | Silent (SNP) | VAF 159/379 reads (42%) | catalogued as COSV63305210; called by muse, mutect2, varscan2
- WDR53 | c.759C>T p.S253= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as COSV60285116; called by muse, mutect2, varscan2
- ZFP30 | c.918C>T p.A306= | Silent (SNP) | VAF 55/119 reads (46%) | catalogued as COSV63623197, COSV63623285; called by muse, mutect2, varscan2
- ZNF227 | c.1221C>T p.P407= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as COSV100480419, COSV57313868; called by muse, mutect2, varscan2
- ZNF239 | c.756C>T p.I252= | Silent (SNP) | VAF 55/155 reads (35%) | catalogued as rs1326287671, COSV60019917; called by muse, mutect2, varscan2
- ZSCAN2 | c.1659G>A p.L553= | Silent (SNP) | VAF 62/144 reads (43%) | catalogued as COSV57572796; called by muse, mutect2, varscan2
- DNAH8 | c.-157G>A | 5'UTR (SNP) | VAF 92/152 reads (61%) | catalogued as COSV59484059; called by muse, varscan2
- NDUFV3 | c.170-5367C>T | Intron (SNP) | VAF 75/156 reads (48%) | catalogued as COSV61088686; called by muse, mutect2, varscan2
- OR2U1P | n.36C>T | RNA (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- SNORD116-19 | n.77C>T | RNA (SNP) | VAF 60/162 reads (37%) | catalogued as rs373804367; called by muse, mutect2, varscan2
